HCMI case HCM-CSHL-1096-C44 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Skin. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/c156af60-87f6-496a-b847-33ed9c51ac18

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Days to birth: -31,512 days (86.3 years before the index date); Year of birth: 1934; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C44.92; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 56 days; Days to treatment end: 106 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 231 days; Days to treatment end: 252 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 363 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease.
2. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; ICD-10 code: C79.89; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Parotid gland; Classification of tumor: metastasis; Days to diagnosis: 62 days.

Follow-up (2 entries)
- Days to follow up: 363 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 222.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 89.8 kg; Height: 177.8 cm; BMI: 28.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-CSHL-1096-C44-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-1096-C44-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
